CCDI case PBCHEY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/028c2734-bb5d-4510-a00c-40e8899825e8

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebrum; Age at diagnosis: 9.8 years (3,597 days).

Biospecimens (3 samples)
- Sample 0DSCOC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSCOV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSCP5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
